CMI case MBCProject_1493 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/63867499-ed45-404c-9ce7-31d9da69063b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (1 sample)
- Sample MBCProject_1493_T1_RNA: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
